Gene-level copy-number profile of tumor specimen HCM-CSHL-0322-C20-01B from HCMI case HCM-CSHL-0322-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 69.1 years (25,229 days).
Specimen HCM-CSHL-0322-C20-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 367c5713-6517-4794-9fe2-0c1471b26d06.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0322-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/cc19148c-7765-48ae-a632-7664debd204f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 62; copy number 2: 4,193; copy number 3: 21,735; copy number 4: 26,237; copy number 5: 2,294; copy number 6: 1,056; copy number 7: 298; copy number 8: 115; copy number 9: 799; copy number 10: 1,030; copy number 11: 21; copy number 13: 456; copy number 14: 61; copy number 15: 25; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,378,679–12,380,265, 1 gene (within-gene range 0–2): AC087203.2.
- chr11:1,662,584–1,663,343, 1 gene: AP006285.1.
- chr15:40,929,340–40,939,073, 1 gene: DLL4.
- chr22:25,279,529–25,282,674, 1 gene: AL022332.1.
- chr22:25,327,252–25,339,975, 1 gene: AL022324.1.
- chr22:25,448,105–25,520,854, 3 genes (within-gene range 0–1): CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,393 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:55,102,028–56,656,496, 33 genes, copy number 9: XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1.
- chr8:69,834,111–69,938,400, 6 genes, copy number 9 (within-gene range 5–9): AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1.
- chr8:114,282,067–114,318,911, 2 genes, copy number 11: AC064802.1, AC025881.1.
- chr8:142,089,827–142,834,940, 28 genes, copy number 9 (within-gene range 6–9): AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3.
- chr11:1,947,278–1,984,522, 1 gene, copy number 27 (within-gene range 4–27): MRPL23.
- chr13:18,467,172–52,489,216, 685 genes, copy number 9–15 (broad region; genes not listed).
- chr13:52,497,097–52,500,195, 1 gene, copy number 10: AL137058.3.
- chr13:66,218,250–114,337,626, 545 genes, copy number 9–14 (broad region; genes not listed).
- chr20:16,982,831–26,251,546, 224 genes, copy number 10 (broad region; genes not listed).
- chr20:30,294,550–64,327,972, 867 genes, copy number 9–11 (broad region; genes not listed).
- chr21:22,500,604–22,520,058, 1 gene, copy number 9: AP000959.1.

Autosomal genes at a single copy (total copy number 1): 62. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
